Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA2G, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA2G-01A (Primary Tumor).

Female
Surgery Date:

DIAGNOSIS:

Liver, right lobe and segment 1, partial hepatectomy: Grade 3 (of 4) cholangiocarcinoma forming a circumscribed mass (3.6 x 2.9 x 2.8 cm) within the region of the caudate lobe. Surgical margins are negative (by 0.2 cm).

Liver, segment 3, No.2, excision: Bile duct adenoma.

Liver, segment 3, biopsy: Benign liver parenchyma, negative for tumor.

Liver, segment 4, biopsy: Benign liver and foci of hemosiderin-laden macrophages. No evidence of neoplasm.

Lymph nodes, hepatic artery, excision: Non-necrotizing granulomatous inflammation. Negative for tumor.

Gallbladder, cholecystectomy: Benign gallbladder mucosa with cholesterosis. No stones are identified. No cystic duct lymph node identified.

Sections of the non-neoplastic liver show prominent non-necrotizing granulomatous infiltrates within portal areas and the lobular parenchyma. There is no apparent fibrosis or ductopenia, and in general the granulomatous infiltrates do not appear to be directed at bile ducts. This likely represents a granulomatous reaction to the patient's neoplasm. However, obtaining an AMA would be helpful to exclude PBC. In addition, there is granulomatous inflammation within the hilar lymph nodes. GMS and AR stains are negative.

Additional clinical correlation needed to exclude other granulomatous processes, such as sarcoidosis.

ICD O3

Cholangiocarcinoma S160/3
Site Intrahepatic bile duct C22.1
9/23/14

Source: NCI Genomic Data Commons file 8a25c1ca-aa93-4fe8-b7eb-c5dcf1ff9e12 (TCGA-W5-AA2G.1E7EDF0B-283F-44F9-A89A-83DB12A0D58A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).